Somatic mutation profile of tumor specimen ALCH-B2LL-TTP1-A (aliquot ALCH-B2LL-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2LL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.5 years (22,845 days).
Specimen ALCH-B2LL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b4d1674-dd0d-4001-95fc-5d8a0f1006b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2LL-NB1-A (Blood Derived Normal), aliquot ALCH-B2LL-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1276c862-8b98-4b13-b3e2-4df1b714b7aa

The open-access MAF lists 47 somatic variants for this specimen: 30 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, 3'UTR 3, Splice Site 2, RNA 2, Frame Shift Ins 1, 5'UTR 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 50/381 reads (13%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | catalogued as rs760298114; called by pindel, varscan2
- CUBN | c.5149G>A p.V1717I | Missense Mutation (SNP) | VAF 48/826 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs769662282, COSV64712705; called by muse, mutect2
- CWC15 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs958878692, COSV54412451, COSV99688573; called by muse, mutect2, varscan2
- KMT2E | c.4771C>A p.P1591T | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV57577482; called by muse, mutect2, varscan2
- LLCFC1 | c.419G>A p.R140Q (on ENST00000458732; = p.R109Q on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.043); catalogued as rs997248326, COSV62338829; called by muse, mutect2
- SLC26A4 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 37/384 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.409); catalogued as rs1286461030; called by muse, mutect2
- SNX19 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV99772870; called by muse, mutect2
- ZNF711 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773043806; called by muse, mutect2, varscan2
- ABCA12 | c.1783-1G>T p.X595_splice (on ENST00000272895 / NM_173076.3; = p.X277_splice on NM_015657.3) | Splice Site (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- ABHD15 | c.1033G>T p.V345F | Missense Mutation (SNP) | VAF 75/376 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ARHGAP4 | c.2452G>A p.A818T | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- ARHGAP4 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- ARHGEF12 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2
- CDH12 | c.698A>C p.Y233S | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP63 | c.1531T>C p.S511P | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); called by muse, mutect2
- COL7A1 | c.3899T>C p.F1300S | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2
- CYP7B1 | c.1173C>A p.D391E | Missense Mutation (SNP) | VAF 25/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOP1B | c.5566A>G p.N1856D | Missense Mutation (SNP) | VAF 34/392 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2
- F13B | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- FAT4 | c.14488A>C p.N4830H | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GAPDHS | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NAE1 | c.1155C>G p.S385R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, varscan2
- NCOA6 | c.3806G>A p.G1269D | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NYNRIN | c.476T>A p.V159E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.961A>T p.I321L (on ENST00000259318 / NM_001136562.3; = p.I552L on NM_007203.5) | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TCF25 | c.1382-2A>T p.X461_splice | Splice Site (SNP) | VAF 22/194 reads (11%) | called by muse, mutect2, varscan2
- UGT8 | c.1421dup p.L474Ffs*36 | Frame Shift Ins (INS) | VAF 28/274 reads (10%) | called by mutect2, pindel
- USP47 | c.3997A>G p.N1333D (on ENST00000399455 / NM_001372095.1; = p.N1245D on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2
- VWA8 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ARHGAP4 | c.2037G>A p.R679= | Silent (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2
- ARHGAP4 | c.1842G>A p.V614= | Silent (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- C6 | c.756A>C p.T252= | Silent (SNP) | VAF 13/223 reads (6%) | catalogued as COSV54709941; called by muse, mutect2
- FCAMR | c.844C>A p.R282= | Silent (SNP) | VAF 17/205 reads (8%) | catalogued as rs761593099; called by muse, mutect2
- ITGA8 | c.1668G>A p.T556= | Silent (SNP) | VAF 16/169 reads (9%) | catalogued as rs748890510; called by muse, mutect2
- MMP14 | c.43C>T p.L15= | Silent (SNP) | VAF 21/212 reads (10%) | called by muse, mutect2
- NRG3 | c.1923C>T p.S641= (on ENST00000404547 / NM_001370084.1; = p.S617= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 27/333 reads (8%) | catalogued as rs148300013; called by muse, mutect2
- NTNG1 | c.1383C>A p.G461= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- SMAD5 | c.1263A>T p.G421= | Silent (SNP) | VAF 32/269 reads (12%) | called by muse, mutect2, varscan2
- SYT5 | c.871C>A p.R291= | Silent (SNP) | VAF 22/320 reads (7%) | catalogued as COSV62830068; called by muse, mutect2
- TREX1 | c.759C>T p.H253= (on ENST00000625293 / NM_033629.6; = p.H243= on NM_007248.5) | Silent (SNP) | VAF 54/603 reads (9%) | called by muse, mutect2
- CTNS | c.*407T>G | 3'UTR (SNP) | VAF 26/255 reads (10%) | called by muse, mutect2, varscan2
- GINM1 | c.-27G>T | 5'UTR (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2
- MSL3P1 | n.1028G>A | RNA (SNP) | VAF 34/341 reads (10%) | catalogued as rs776789152; called by muse, mutect2, varscan2
- OR3A4P | n.439C>T | RNA (SNP) | VAF 36/372 reads (10%) | catalogued as rs765567710; called by muse, mutect2
- RAB18 | c.*3330G>T | 3'UTR (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- TAF10 | c.*1884C>T | 3'UTR (SNP) | VAF 48/628 reads (8%) | called by muse, mutect2
